FM case AD6744 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas.
https://portal.gdc.cancer.gov/cases/db81fe07-414f-4c7c-88c9-bc5769e933b9

Male, 65.9 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3); specimen biopsied or resected from the pelvis. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
